Somatic mutation profile of tumor specimen TCGA-HR-A2OG-06A (aliquot TCGA-HR-A2OG-06A-21D-A197-08) from TCGA case TCGA-HR-A2OG, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.6 years (21,767 days).
Specimen TCGA-HR-A2OG-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 633e735b-22fd-47c5-ad45-8956c932ad44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HR-A2OG-10A (Blood Derived Normal), aliquot TCGA-HR-A2OG-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df3f3eb0-e8c3-4d12-9a10-435efac6eb68

The open-access MAF lists 222 somatic variants for this specimen: 153 protein-altering or splice-affecting, 62 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 62, Nonsense Mutation 11, Splice Region 3, RNA 3, Frame Shift Del 2, 3'UTR 2, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 108/178 reads (61%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD12 | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.296); catalogued as COSV59289080; called by muse, mutect2, varscan2
- ACBD5 | c.1177C>T p.R393W (on ENST00000375888 / NM_001352568.1; = p.R384W on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs149955149, COSV65520791, COSV65521328; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS19 | c.2973G>A p.W991* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | catalogued as COSV50749056, COSV50772259; called by muse, mutect2, varscan2
- ANKS4B | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.048); catalogued as rs779830541, COSV61140345; called by muse, mutect2
- AP1G1 | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 70/302 reads (23%) | catalogued as COSV55495337; called by mutect2, varscan2
- APOBEC1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV57550258; called by muse, mutect2, varscan2
- AQP6 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100210339; called by muse, mutect2, varscan2
- ARHGEF40 | c.2473C>T p.R825C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1190876307, COSV100070744, COSV53884454; called by muse, mutect2, varscan2
- ASH1L | c.2096G>A p.S699N | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.001); catalogued as COSV64213940; called by muse, mutect2, varscan2
- ASPM | c.6962C>T p.S2321L | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.241); catalogued as COSV54138861; called by muse, mutect2, varscan2
- ATP7B | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54444448; called by muse, mutect2, varscan2
- ATR | c.5370T>A p.Y1790* | Nonsense Mutation (SNP) | VAF 51/153 reads (33%) | catalogued as COSV63392495; called by muse, mutect2, varscan2
- BAZ2B | c.2186C>T p.P729L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.185); catalogued as COSV58610202; called by muse, mutect2, varscan2
- BEST3 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99876429; called by muse, mutect2, varscan2
- BMP15 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as rs782378869, COSV53142031; called by muse, mutect2, varscan2
- BRD4 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.055); catalogued as rs201937726, COSV54595303; called by muse, mutect2, varscan2
- BTAF1 | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV56439574; called by muse, mutect2, varscan2
- C1QTNF2 | c.782G>A p.G261D (on ENST00000393975; = p.G216D on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67433352; called by mutect2, varscan2
- C6orf47 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as rs779432813, COSV63264170; called by muse, mutect2, varscan2
- C7 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as rs762730761, COSV57475376, COSV57481219; called by muse, mutect2, varscan2
- CAD | c.6335C>T p.P2112L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53032015; called by muse, mutect2, varscan2
- CAGE1 | c.1000G>A p.E334K (on ENST00000512086; = p.E198K on NM_205864.3) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV57082267; called by muse, mutect2, varscan2
- CCR2 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 40/347 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.611); catalogued as rs539087679, COSV52748389; called by muse, mutect2, varscan2
- CD96 | c.889C>T p.P297S (on ENST00000283285 / NM_198196.3; = p.P281S on NM_005816.5) | Missense Mutation (SNP) | VAF 106/323 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51918940; called by muse, mutect2, varscan2
- CDCA2 | c.2498C>T p.S833F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57948671; called by muse, mutect2, varscan2
- CFAP221 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs777051013, COSV54662812; called by muse, mutect2, varscan2
- CFAP54 | c.7588C>T p.R2530C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV61573171; called by muse, mutect2, varscan2
- CFH | c.3320G>A p.G1107E | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as rs754500480, COSV66406878; called by muse, mutect2, varscan2
- CLCN1 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.972); catalogued as COSV58374543; called by mutect2, varscan2
- CNN1 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs751322838, COSV52956987; called by mutect2, varscan2
- COG4 | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.28); catalogued as COSV56791106; called by muse, mutect2, varscan2
- COL4A6 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57878545; called by muse, mutect2, varscan2
- COL4A6 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1437021259, COSV57878567; called by muse, mutect2, varscan2
- COL5A3 | c.5137C>T p.R1713* | Nonsense Mutation (SNP) | VAF 24/86 reads (28%) | catalogued as rs778778214, COSV53414853, COSV53415695; called by muse, mutect2, varscan2
- CRELD1 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99926799; called by muse, mutect2, varscan2
- CRELD1 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99926801; called by muse, mutect2, varscan2
- CYSLTR2 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV56167021; called by muse, mutect2, varscan2
- DENND4A | c.2936C>T p.S979L | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs765292883, COSV71267037; called by muse, mutect2, varscan2
- DGAT2L6 | c.63G>A p.W21* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as rs759764588, CM134661, COSV60718799; called by muse, mutect2, varscan2
- DMXL2 | c.3373C>T p.L1125F | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51856462; called by muse, mutect2, varscan2
- DNAH3 | c.4792C>T p.H1598Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54515111; called by mutect2, varscan2
- EDNRB | c.763G>A p.E255K (on ENST00000377211 / NM_001201397.1; = p.E165K on NM_000115.5) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV57528114; called by muse, mutect2
- EIF2AK2 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV51799467; called by muse, mutect2, varscan2
- ELAPOR2 | c.874C>T p.P292S (on ENST00000450689 / NM_001142749.3; = p.P125S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as COSV51891982; called by muse, mutect2, varscan2
- ELN | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52715827; called by muse, mutect2, varscan2
- F2R | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100058727; called by muse, mutect2, varscan2
- F8 | c.4241C>T p.S1414L | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as CM136648, COSV64278814; called by muse, mutect2, varscan2
- FAM47C | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.674); catalogued as COSV63730324; called by muse, mutect2, varscan2
- FLG | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 226/390 reads (58%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.837); catalogued as rs267598031, CM1513736, COSV64249588; called by muse, mutect2, varscan2
- FOXJ2 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.011); catalogued as COSV50824965; called by muse, mutect2, varscan2
- FREM1 | c.2485G>A p.G829R | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV66523991; called by muse, mutect2, varscan2
- GNPDA2 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs374507605, COSV54948637; called by muse, mutect2, varscan2
- GPBP1 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV53314776; called by muse, mutect2, varscan2
- GPR22 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as rs899079349, COSV99771873; called by muse, mutect2, varscan2
- GRIP1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1406416797, COSV54032398; called by muse, mutect2, varscan2
- GUCY1A1 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56651456; called by mutect2, varscan2
- HEXB | c.1423C>T p.Q475* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV54670062; called by muse, mutect2
- HNF4G | c.779A>G p.K260R (on ENST00000354370 / NM_001330561.2; = p.K307R on NM_004133.5) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.097); catalogued as rs780138892, COSV62973789; called by muse, mutect2, varscan2
- HORMAD1 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV59273289; called by muse, mutect2
- HRNR | c.7064C>A p.T2355N | Missense Mutation (SNP) | VAF 118/1102 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100914041; called by muse, mutect2, varscan2
- IGFBP5 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.352); catalogued as rs757553693, COSV99289081, COSV99289112; called by muse, mutect2, varscan2
- IGKV2-30 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as rs1468022808; called by mutect2, varscan2
- INHBA | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV54225360; called by muse, mutect2, varscan2
- IRAG2 | c.4120G>A p.V1374I (on ENST00000636465; = p.V419I on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV57236875; called by mutect2, varscan2
- ITGA4 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV99276955; called by muse, mutect2, varscan2
- KCNC2 | c.1121C>T p.T374I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54380109; called by muse, mutect2, varscan2
- KIAA2026 | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV67356700, COSV67357808; called by mutect2, varscan2
- KNG1 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV53981077, COSV53981149; called by muse, mutect2, varscan2
- KRT12 | c.480G>A p.W160* | Nonsense Mutation (SNP) | VAF 19/121 reads (16%) | catalogued as COSV52432482; called by muse, mutect2, varscan2
- KRT15 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV54182016; called by muse, mutect2
- L3MBTL2 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as COSV53435796; called by muse, mutect2, varscan2
- LIN52 | c.135T>C p.P45= | Splice Region (SNP) | VAF 9/32 reads (28%) | catalogued as COSV73465966; called by muse, mutect2, varscan2
- LRP1 | c.8096A>C p.N2699T | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.649); catalogued as COSV54526117; called by muse, mutect2, varscan2
- MAGED1 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.456); catalogued as rs782539728, COSV58516917; called by mutect2, varscan2
- MAP4 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV64244745; called by muse, mutect2, varscan2
- MB21D2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV66666088; called by muse, mutect2, varscan2
- MMAA | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV99850110; called by muse, mutect2
- MMAA | c.510A>C p.R170S | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV99850112; called by muse, mutect2, varscan2
- MSL3 | c.886G>A p.E296K (on ENST00000312196 / NM_078629.4; = p.E130K on NM_006800.4) | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); catalogued as COSV56496231; called by muse, mutect2, varscan2
- MTMR12 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV53788168; called by muse, mutect2, varscan2
- MYLK | c.2860C>T p.R954C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749847711, COSV60609949; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.5492G>A p.G1831E | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM074375, COSV52764344; called by muse, mutect2, varscan2
- NBR1 | c.799T>G p.S267A | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100358038; called by mutect2, varscan2
- NFIL3 | c.1346G>A p.R449K | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV52684758; called by muse, mutect2, varscan2
- NLRC5 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52663288; called by muse, mutect2, varscan2
- NPY2R | c.161T>A p.I54K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61529602; called by muse, mutect2, varscan2
- NUP210 | c.3200G>A p.R1067K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99596234; called by muse, mutect2
- NUTM1 | c.1969G>A p.G657R | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs376033444, COSV59219099; called by muse, mutect2, varscan2
- OCRL | c.1227G>T p.L409F | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV63981897; called by muse, varscan2
- OLFM1 | c.524C>T p.A175V (on ENST00000371793 / NM_001282611.2; = p.A157V on NM_014279.5) | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.541); catalogued as COSV52963722; called by muse, mutect2, varscan2
- OR2Z1 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV60691984, COSV60692689; called by muse, mutect2, varscan2
- OR5H14 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.651); catalogued as COSV71193905, COSV71194557; called by muse, mutect2
- OR5T1 | c.637T>C p.Y213H | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.078); catalogued as COSV57302591; called by muse, mutect2, varscan2
- PAK3 | c.1385C>T p.S462F (on ENST00000262836 / NM_001324328.2; = p.S447F on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53280798; called by muse, mutect2, varscan2
- PCDH10 | c.35T>G p.M12R | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs750687431, COSV52104113; called by muse, mutect2, varscan2
- PCDHGA7 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as rs371173445; called by muse, mutect2, varscan2
- PIGU | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.25); catalogued as COSV54166692; called by muse, varscan2
- PLEKHA4 | c.1838C>T p.S613F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); catalogued as rs1233929848, COSV54362158, COSV54366717; called by muse, mutect2, varscan2
- PLG | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV51981310; called by muse, mutect2, varscan2
- PLPPR1 | c.817A>G p.M273V | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66457883; called by muse, mutect2, varscan2
- PPP6C | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 23/46 reads (50%) | catalogued as rs865855853, COSV65207519; called by mutect2, varscan2
- PPRC1 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs780690524, COSV53388625; called by muse, varscan2
- PSG6 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 111/299 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as COSV51830662, COSV99413742; called by muse, mutect2, varscan2
- PTPN4 | c.2513G>A p.R838Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs761088036, COSV55305195, COSV55309358; called by muse, mutect2, varscan2
- PTPRK | c.1652G>A p.W551* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100951112, COSV63907440; called by muse, mutect2, varscan2
- RADIL | c.1420A>C p.K474Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as COSV68203748; called by muse, mutect2, varscan2
- RAPGEF3 | c.832G>A p.D278N (on ENST00000389212; = p.D236N on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1388099441, COSV50241041, COSV99060320; called by muse, mutect2, varscan2
- RASGRF1 | c.1328T>A p.I443N | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV69183376; called by muse, mutect2, varscan2
- RBBP8 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100507745; called by muse, mutect2, varscan2
- RBBP8 | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.318); catalogued as COSV100507748; called by muse, mutect2, varscan2
- RNF2 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62280557; called by muse, mutect2, varscan2
- SDK2 | c.5417T>G p.F1806C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV66197207; called by muse, mutect2, varscan2
- SERINC3 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV54858597; called by muse, mutect2
- SLC1A1 | c.1562C>T p.T521I | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV52058125; called by muse, mutect2, varscan2
- SLC26A8 | c.1859C>T p.P620L | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV62887723; called by muse, varscan2
- SLC39A10 | c.386A>T p.Q129L | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV62766756, COSV62769608; called by muse, mutect2, varscan2
- SLC39A10 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV62769614; called by muse, mutect2, varscan2
- SLC4A4 | c.1280G>A p.G427E (on ENST00000264485 / NM_001098484.3; = p.G383E on NM_003759.4) | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.053); catalogued as COSV52619639; called by muse, mutect2, varscan2
- SLC5A1 | c.614C>T p.T205I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.517); catalogued as COSV56686774; called by mutect2, varscan2
- SLC9C1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs749177716, COSV59886093; called by muse, mutect2, varscan2
- SLITRK2 | c.1628G>A p.W543* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as COSV59428819; called by muse, mutect2, varscan2
- SLX4 | c.2918C>T p.S973F | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV53568735; called by muse, mutect2, varscan2
- SPPL3 | c.1138C>G p.R380G | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV62234432; called by muse, mutect2, varscan2
- SPTBN4 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58960914; called by muse, mutect2, varscan2
- STAG3 | c.2952G>A p.K984= | Splice Region (SNP) | VAF 38/136 reads (28%) | catalogued as COSV57935102; called by muse, mutect2, varscan2
- STAT6 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs776930978, COSV55674232; called by muse, mutect2, varscan2
- SUN3 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs771226333, COSV52051476; called by muse, mutect2, varscan2
- SVOPL | c.973G>A p.G325R (on ENST00000419765; = p.G173R on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV55995419; called by muse, mutect2, varscan2
- SYT16 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV70859960; called by muse, mutect2, varscan2
- TAF4 | c.2623C>T p.Q875* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as COSV53343380; called by muse, mutect2
- TBC1D9 | c.3429C>G p.N1143K | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.031); catalogued as COSV71306991, COSV71308985; called by muse, mutect2, varscan2
- TCAF2 | c.924A>T p.K308N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV100633756; called by mutect2, varscan2
- TFDP3 | c.839T>G p.F280C | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59538539; called by muse, mutect2, varscan2
- TMEM72 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs756225702, COSV67461299; called by muse, varscan2
- TNFRSF10D | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV57035056; called by muse, mutect2, varscan2
- TPRX1 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV59117416; called by mutect2, varscan2
- TRPC5 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV53303168; called by muse, mutect2, varscan2
- TTC16 | c.2387G>A p.R796K | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV60162211; called by muse, mutect2, varscan2
- TTLL4 | c.3421G>A p.G1141S | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as COSV51439517; called by muse, mutect2, varscan2
- TTN | c.21427A>G p.R7143G (on ENST00000591111; = p.R6216G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | PolyPhen benign (0.121); catalogued as COSV60355045; called by muse, mutect2, varscan2
- TTN | c.8197C>T p.P2733S (on ENST00000591111; = p.P2687S on NM_003319.4) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | PolyPhen benign (0.242); catalogued as rs1407570813, COSV100634779; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2197C>T p.R733C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1025338905, COSV51957315; called by muse, mutect2, varscan2
- VIL1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1559146651, COSV50298073; called by muse, varscan2
- VWF | c.5125G>A p.E1709K | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs768448504, COSV54633782; called by muse, mutect2, varscan2
- ZFHX4 | c.7044A>T p.Q2348H | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as COSV51496771; called by mutect2, varscan2
- ZFPM2 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV65875978, COSV99059178; called by muse, mutect2
- ZNF470 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV57970812; called by muse, mutect2, varscan2
- ZNF99 | c.1826G>A p.R609K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV68056809, COSV68057090; called by muse, mutect2, varscan2
- FSD1 | c.650A>G p.Q217R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2
- TBC1D5 | c.1388del p.N463Ifs*6 | Frame Shift Del (DEL) | VAF 19/42 reads (45%) | called by mutect2, varscan2
- TFPI | c.536-3dup | Splice Region (INS) | VAF 10/62 reads (16%) | called by mutect2, pindel
- ZNF774 | c.1253_1254del p.F418Yfs*17 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- ALMS1 | c.9648T>C p.S3216= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV52522336; called by muse, mutect2, varscan2
- ANK3 | c.13092G>A p.T4364= (on ENST00000280772 / NM_001320874.2; = p.T988= on NM_001149.3) | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as rs775425679, COSV55046749; called by mutect2, varscan2
- AQP6 | c.252C>T p.A84= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs147805945; called by mutect2, varscan2
- ARHGAP26 | c.309G>A p.R103= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV50841670; called by muse, mutect2, varscan2
- ATRN | c.2085C>T p.S695= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV53533979; called by muse, mutect2, varscan2
- AZI2 | c.1146T>C p.D382= | Silent (SNP) | VAF 37/132 reads (28%) | catalogued as COSV55425478; called by muse, varscan2
- BFSP1 | c.1149C>T p.N383= | Silent (SNP) | VAF 54/148 reads (36%) | catalogued as rs758874244, COSV64899199; called by mutect2, varscan2
- CD99L2 | c.714A>G p.E238= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV60938561; called by muse, mutect2, varscan2
- CLIP2 | c.858C>T p.I286= | Silent (SNP) | VAF 37/170 reads (22%) | catalogued as rs1554308486, COSV56286415; called by muse, mutect2, varscan2
- CSMD1 | c.3066G>A p.R1022= (on ENST00000520002; = p.R1021= on NM_033225.6) | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV59384472; called by muse, mutect2, varscan2
- CTNNA2 | c.702C>T p.A234= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs779761149, COSV63569973; called by muse, mutect2, varscan2
- CUTA | c.300C>T p.I100= (on ENST00000488034 / NM_001014840.2; = p.I77= on NM_015921.3) | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV53386747; called by mutect2, varscan2
- DEFB125 | c.288G>A p.L96= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as COSV66703658; called by muse, mutect2, varscan2
- DLST | c.1167T>C p.P389= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV53167921; called by muse, mutect2, varscan2
- DNM2 | c.792C>T p.A264= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV58972123; called by muse, mutect2, varscan2
- DST | c.9454T>C p.L3152= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as COSV99760905; called by mutect2, varscan2
- EBF2 | c.1521T>C p.P507= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs768097516, COSV68780635; called by muse, mutect2, varscan2
- ECE2 | c.114G>A p.P38= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs373518539; called by muse, mutect2, varscan2
- EDC4 | c.1695C>T p.S565= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV62768037; called by muse, mutect2, varscan2
- F2R | c.720G>A p.K240= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV100058725; called by muse, mutect2, varscan2
- GP1BA | c.585C>T p.L195= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV56700899; called by muse, mutect2, varscan2
- GPR22 | c.306C>A p.I102= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as rs1036638774, COSV99773507; called by mutect2, varscan2
- HRNR | c.7065T>A p.T2355= | Silent (SNP) | VAF 116/1092 reads (11%) | catalogued as COSV100914040; called by muse, mutect2, varscan2
- IGHG4 | c.408C>T p.T136= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs751794651; called by muse, mutect2, varscan2
- IGKV2-24 | c.306G>A p.R102= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as rs765160922; called by muse, mutect2, varscan2
- IGSF10 | c.1194G>A p.P398= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs146034413, COSV99176536; called by mutect2, varscan2
- IL13RA2 | c.1011G>A p.S337= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs368591186, COSV54563891; called by muse, mutect2, varscan2
- KATNIP | c.582G>A p.R194= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV55192119, COSV99850635; called by muse, mutect2, varscan2
- KCNH6 | c.2619C>T p.A873= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV59007718; called by muse, mutect2, varscan2
- KRT23 | c.180T>C p.G60= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as COSV52929063; called by muse, mutect2, varscan2
- LAMA2 | c.2685C>T p.G895= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as COSV101370944; called by muse, mutect2, varscan2
- LRRC4 | c.1386G>A p.T462= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as COSV50818752; called by muse, mutect2, varscan2
- MFSD9 | c.1113C>T p.A371= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV51495767; called by muse, mutect2, varscan2
- MYH4 | c.720G>A p.R240= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV55126468; called by muse, mutect2, varscan2
- NLRP4 | c.2088G>A p.L696= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV56708298; called by muse, mutect2, varscan2
- NPY5R | c.132G>A p.L44= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV100642868, COSV58453947; called by muse, mutect2, varscan2
- OPN4 | c.895C>T p.L299= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs777881931, COSV54119830; called by muse, mutect2, varscan2
- OR10AG1 | c.465C>T p.F155= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as COSV56631984; called by muse, mutect2, varscan2
- PARP12 | c.1329C>T p.F443= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs373525023; called by muse, mutect2
- PCARE | c.2580G>A p.K860= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs1248007781, COSV59055612; called by muse, mutect2, varscan2
- PCSK5 | c.5250C>T p.S1750= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as COSV70452809; called by muse, mutect2
- PEG3 | c.3102G>A p.K1034= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV55648089; called by muse, mutect2, varscan2
- PRRG1 | c.474C>T p.S158= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs1350012774, COSV66158147; called by muse, mutect2
- PTCD1 | c.1636C>T p.L546= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99464698; called by muse, varscan2
- PTCD1 | c.1635C>T p.V545= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99464703; called by muse, varscan2
- RTL1 | c.288C>T p.L96= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as COSV66017525; called by muse, mutect2, varscan2
- SH3PXD2B | c.1575G>A p.R525= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV61130275; called by mutect2, varscan2
- SIGLEC5 | c.711G>A p.Q237= | Silent (SNP) | VAF 35/153 reads (23%) | catalogued as COSV55784073; called by muse, mutect2, varscan2
- SLC25A27 | c.226C>T p.L76= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as COSV51499379; called by muse, mutect2, varscan2
- SLC36A1 | c.204C>T p.L68= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV54651851; called by muse, mutect2, varscan2
- SLC47A2 | c.645C>T p.I215= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV57630633; called by muse, mutect2, varscan2
- SNCAIP | c.2697G>A p.R899= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as COSV54421704; called by muse, mutect2, varscan2
- SORCS2 | c.2025C>T p.F675= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV61183592; called by muse, mutect2, varscan2
- SPP1 | c.318C>T p.N106= (on ENST00000395080 / NM_001040058.2; = p.N92= on NM_000582.2) | Silent (SNP) | VAF 26/229 reads (11%) | catalogued as rs150169219; called by muse, mutect2, varscan2
- SPTBN4 | c.1020C>T p.S340= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV100152402; called by muse, mutect2, varscan2
- TNXB | c.8343C>T p.S2781= (on ENST00000647633; = p.S2534= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/274 reads (17%) | catalogued as COSV64476725; called by muse, mutect2, varscan2
- TTN | c.8196C>T p.H2732= (on ENST00000591111; = p.H2686= on NM_003319.4) | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV100634780; called by muse, mutect2, varscan2
- UGT2B17 | c.126C>T p.I42= | Silent (SNP) | VAF 135/218 reads (62%) | catalogued as COSV58502683; called by muse, mutect2, varscan2
- VPS50 | c.1434C>T p.F478= | Silent (SNP) | VAF 40/210 reads (19%) | catalogued as COSV58511333; called by muse, mutect2, varscan2
- ZCRB1 | c.363G>C p.P121= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV56892337; called by muse, mutect2, varscan2
- ZNF285 | c.273C>T p.I91= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as rs200246187, COSV58408188; called by muse, mutect2, varscan2
- ZNFX1 | c.2983C>T p.L995= | Silent (SNP) | VAF 115/267 reads (43%) | catalogued as COSV65579343; called by muse, mutect2, varscan2
- AL136982.4 | n.1581G>A | RNA (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
- CDKL1 | n.123C>T | RNA (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- LRP2BP | c.-1G>A | 5'UTR (SNP) | VAF 36/94 reads (38%) | catalogued as rs1210064817, COSV100146074; called by muse, mutect2, varscan2
- MIR487B | n.54C>T | RNA (SNP) | VAF 9/43 reads (21%) | catalogued as rs1402013521; called by muse, mutect2, varscan2
- PRR12 | chr19:49594525 C>T | 5'Flank (SNP) | VAF 15/77 reads (19%) | catalogued as COSV55871772; called by muse, mutect2, varscan2
- RAET1E | c.*2C>T | 3'UTR (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100593552; called by mutect2, varscan2
- VNN3 | c.*668G>A | 3'UTR (SNP) | VAF 6/35 reads (17%) | catalogued as COSV51592630; called by muse, mutect2, varscan2
